Gene-level copy-number profile of tumor specimen TARGET-20-PARDMG-04A from TARGET case TARGET-20-PARDMG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,535 days).
Specimen TARGET-20-PARDMG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.b1dd4b8a-1c63-56fa-b804-5622e0fd6045.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARDMG-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/e5e6f525-176c-4e04-a581-d754263ed964

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 547; copy number 1: 1,063; copy number 2: 58,449; copy number 3: 11; copy number 4: 3; copy number 5: 85; copy number 6: 1; copy number 7: 114.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,687,085–242,160,153, 23 genes (within-gene range 0–2): ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5, LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:51,966,742–51,967,149, 1 gene, copy number 5: FABP5P2.
- chr13:111,095,838–111,113,697, 2 genes, copy number 5 (within-gene range 2–5): LINC00368, AL353704.2.
- chr14:18,333,726–19,936,757, 82 genes, copy number 5 (broad region; genes not listed).
- chr14:105,836,765–106,443,583, 114 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,063. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
